Somatic mutation profile of tumor specimen TCGA-RW-A67V-01A (aliquot TCGA-RW-A67V-01A-11D-A35D-08) from TCGA case TCGA-RW-A67V, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 44.2 years (16,139 days).
Specimen TCGA-RW-A67V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65218bd8-c1db-48fe-bba1-0a5e957dd8a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A67V-10A (Blood Derived Normal), aliquot TCGA-RW-A67V-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21b306a0-6171-4cfc-934d-16396240ec0b

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DHX37 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as rs1481032140; called by muse, mutect2, varscan2
- KATNIP | c.2426G>A p.R809Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs1286736049, COSV55176926; called by muse, mutect2, varscan2
- SHISA2 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs769814800, COSV100096652; called by muse, mutect2, varscan2
- SPDYA | c.931A>C p.S311R | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as rs748286752; called by muse, mutect2, varscan2
- C12orf45 | c.284C>G p.P95R | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- PUM2 | c.2003G>A p.G668E | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SZT2 | c.7040C>G p.S2347* (on ENST00000634258 / NM_001365999.1; = p.S2290* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 16/20 reads (80%) | called by muse, mutect2, varscan2
- TTN | c.75335A>G p.Y25112C (on ENST00000591111; = p.Y17688C on NM_003319.4) | Missense Mutation (SNP) | VAF 13/145 reads (9%) | PolyPhen probably damaging (0.994); called by muse, mutect2
- WDR20 | c.741C>G p.F247L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- CNTNAP3 | c.363G>A p.K121= | Silent (SNP) | VAF 10/12 reads (83%) | called by mutect2, varscan2
- RAB11B | c.60A>G p.S20= | Silent (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
